Gene-level copy-number profile of tumor specimen TCGA-W4-A7U2-01A from TCGA case TCGA-W4-A7U2, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 26.2 years (9,573 days).
Specimen TCGA-W4-A7U2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.a6e2b829-855e-4006-877a-c8d73c8c03a4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W4-A7U2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/400e8bd7-294d-4deb-92a1-8ab774789179

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,706; copy number 2: 20,034; copy number 3: 27,309; copy number 4: 9,807; copy number 7: 944; copy number 69: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W4-A7U2-01A-11D-A434-01): tumor purity 0.62, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 958 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:94,352,923–99,013,743, 94 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 7 (broad region; genes not listed).
- chr13:108,596,152–109,986,565, 14 genes, copy number 69 (within-gene range 2–69): MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1.

Autosomal genes at a single copy (total copy number 1): 1,706. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
